Somatic mutation profile of tumor specimen MP2PRT-PAVJBY-TMP1-A (aliquot MP2PRT-PAVJBY-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVJBY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,172 days).
Specimen MP2PRT-PAVJBY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 580a29f2-5af5-4b91-963c-1ac431029ff3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJBY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJBY-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05c7a654-fc94-41a9-a0e2-8ee61c10fa04

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Nonstop Mutation 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CKAP4 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 192/447 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs373878196; called by muse, mutect2, varscan2
- DTD1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs777964321, COSV66280096; called by muse, mutect2, varscan2
- GYG2 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs1191784242; called by muse, mutect2
- MAGEL2 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 191/434 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); catalogued as rs781530773, COSV58569523; called by muse, mutect2, varscan2
- NRXN1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 231/589 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV68029352; called by muse, mutect2, varscan2
- OR4A8 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 134/346 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs759873857; called by muse, mutect2, varscan2
- PAX5 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 142/332 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63905332; called by muse, mutect2, varscan2
- TBX22 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 242/309 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs765734398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS14 | c.209_210insTCGG p.D71Rfs*103 | Frame Shift Ins (INS) | VAF 160/485 reads (33%) | called by mutect2, pindel*
- CACNA1B | c.134A>T p.Y45F | Missense Mutation (SNP) | VAF 158/862 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, varscan2
- PAX5 | c.1174T>C p.*392Rext*111 | Nonstop Mutation (SNP) | VAF 260/661 reads (39%) | called by muse, mutect2, varscan2
- SPTLC1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRAJ47 | c.1_5delinsGG p.E2del | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by muse*, pindel
- UBTF | c.370A>G p.M124V | Missense Mutation (SNP) | VAF 142/345 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF160 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CD22 | c.1170C>T p.H390= | Silent (SNP) | VAF 186/452 reads (41%) | catalogued as rs776075532, COSV50054345; called by muse, mutect2, varscan2
- ENOX1 | c.18A>C p.G6= | Silent (SNP) | VAF 97/266 reads (36%) | called by muse, mutect2
- PDLIM2 | c.702G>A p.A234= (on ENST00000397760; = p.A484= on NM_021630.6) | Silent (SNP) | VAF 145/412 reads (35%) | catalogued as rs373823691; called by muse, mutect2, varscan2
